Somatic mutation profile of tumor specimen TCGA-XF-A9SZ-01A (aliquot TCGA-XF-A9SZ-01A-11D-A391-08) from TCGA case TCGA-XF-A9SZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.7 years (29,100 days).
Specimen TCGA-XF-A9SZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8565f0e9-f6c5-4cfd-a05f-22215806ce70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SZ-10A (Blood Derived Normal), aliquot TCGA-XF-A9SZ-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28ebf72a-c715-43de-842f-74db28c16f1c

The open-access MAF lists 225 somatic variants for this specimen: 173 protein-altering or splice-affecting, 45 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 45, Nonsense Mutation 10, Frame Shift Del 9, Intron 3, 5'Flank 3, Splice Site 2, Splice Region 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX59 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886037652, CM138617, COSV58753683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | hotspot (GDC flag); catalogued as rs3092891, CM900192, CX011720, COSV57295313; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AADAT | c.314G>C p.S105T | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61787926; called by muse, mutect2, varscan2
- AC098582.1 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52023864; called by muse, mutect2, varscan2
- ACLY | c.1990G>T p.G664* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100709588, COSV61249811; called by muse, mutect2, varscan2
- ACP2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.516); catalogued as COSV57043764; called by muse, mutect2, varscan2
- ACTA2 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV56517832; called by muse, mutect2, varscan2
- ADAMTS4 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV63490498, COSV63491023; called by muse, mutect2
- ANKRD12 | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50842023; called by muse, mutect2, varscan2
- ANKRD23 | c.319G>C p.V107L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58413262; called by muse, mutect2, varscan2
- ARID2 | c.5350G>C p.E1784Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as rs1350453834, COSV57612699; called by muse, mutect2, varscan2
- ARL8A | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55344028; called by muse, mutect2
- ARMCX2 | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57530956; called by muse, mutect2
- ARSD | c.354G>T p.W118C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54202614; called by muse, mutect2, varscan2
- AXIN1 | c.1238T>G p.L413R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51992098; called by muse, mutect2, varscan2
- BCL11A | c.239C>G p.A80G | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV59624108; called by muse, mutect2, varscan2
- BLMH | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55586668; called by muse, mutect2, varscan2
- BRWD1 | c.6710T>A p.V2237D | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV59001233; called by muse, mutect2, varscan2
- C6 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706942, COSV54716600; called by muse, mutect2, varscan2
- C9orf64 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1262274371, COSV59033033; called by muse, mutect2, varscan2
- CAMK4 | c.384T>C p.D128= | Splice Region (SNP) | VAF 28/82 reads (34%) | catalogued as COSV56680384; called by muse, mutect2, varscan2
- CATSPER2 | c.1495G>C p.E499Q (on ENST00000321596 / NM_001282309.3; = p.E501Q on NM_172095.4) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.519); catalogued as COSV58661707; called by muse, mutect2, varscan2
- CC2D2A | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101052699; called by muse, mutect2
- CD34 | c.263-1G>C p.X88_splice | Splice Site (SNP) | VAF 24/124 reads (19%) | catalogued as COSV60414674, COSV60414912; called by muse, mutect2, varscan2
- CDC20B | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as COSV57056405; called by muse, mutect2, varscan2
- CHD9 | c.4411G>C p.E1471Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV54612959, COSV54615159, COSV99529580; called by muse, mutect2, varscan2
- CLIP1 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56799621; called by muse, mutect2
- CNTNAP4 | c.2894A>T p.Y965F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV56696962; called by muse, mutect2, varscan2
- CPNE8 | c.1243T>A p.F415I | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV100503720, COSV58850235; called by muse, mutect2, varscan2
- CRB1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as rs1447630642, COSV66331988; called by mutect2, varscan2
- CSF1R | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs1229562677, COSV53841315; called by muse, mutect2, varscan2
- CYP2E1 | c.731A>T p.E244V | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV53314970; called by muse, mutect2, varscan2
- DEF8 | c.248C>G p.S83C (on ENST00000268676 / NM_207514.3; = p.S22C on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV51920984; called by muse, varscan2
- DGKD | c.1817G>C p.R606P (on ENST00000264057 / NM_152879.3; = p.R562P on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs754093994, COSV51033689, COSV51090374; called by muse, mutect2, varscan2
- DHX58 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52427860; called by muse, mutect2, varscan2
- DHX8 | c.3045G>C p.Q1015H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV52255988; called by muse, mutect2, varscan2
- DIP2C | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55175326; called by muse, mutect2, varscan2
- DKK3 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV58869969; called by muse, mutect2, varscan2
- DLGAP3 | c.1220G>C p.G407A | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV52396762; called by muse, mutect2, varscan2
- DLGAP5 | c.2533del p.E845Nfs*22 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as COSV54306320, COSV99582539; called by mutect2, pindel, varscan2
- DMD | c.7248A>T p.L2416F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV58944067; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1936G>A p.V646M (on ENST00000361735 / NM_015935.5; = p.V560M on NM_014955.3) | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62283714; called by muse, mutect2, varscan2
- EHHADH | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51632758; called by muse, mutect2
- EVC | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376396220; called by muse, mutect2
- F10 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.902); catalogued as rs768222784, CM940381, COSV65022764; called by muse, mutect2, varscan2
- FAM151A | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV56364507, COSV56365967; called by muse, mutect2, varscan2
- FAT4 | c.7784C>G p.S2595C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257114277, COSV58689185; called by muse, mutect2, varscan2
- FUCA2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50020760; called by muse, mutect2, varscan2
- GCFC2 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100319461; called by muse, mutect2, varscan2
- GCM2 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM099924, COSV65276268, COSV65276393; called by muse, mutect2, varscan2
- GRM6 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51445385; called by muse, mutect2, varscan2
- GTF2E1 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52202991; called by muse, mutect2, varscan2
- H2AC11 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV60362634; called by muse, mutect2, varscan2
- HCN1 | c.2471G>C p.G824A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV57519543, COSV57532818; called by muse, mutect2, varscan2
- HOXA13 | c.1088A>T p.E363V | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56084004; called by muse, mutect2, varscan2
- HOXA13 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56084013; called by muse, mutect2, varscan2
- HUWE1 | c.5161+1G>A p.X1721_splice | Splice Site (SNP) | VAF 35/79 reads (44%) | catalogued as COSV53361089; called by muse, mutect2, varscan2
- IFIT1B | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV65663691; called by muse, mutect2
- INTS6L | c.1401A>T p.K467N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100878279, COSV66085857; called by muse, mutect2, varscan2
- ITCH | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as COSV52935948; called by muse, mutect2, varscan2
- ITCH | c.1201C>G p.Q401E (on ENST00000262650 / NM_001257137.3; = p.Q360E on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1460138625, COSV52935957; called by muse, mutect2
- ITGAE | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV53998604; called by muse, mutect2, varscan2
- JAK3 | c.2119G>C p.D707H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71687263; called by muse, mutect2, varscan2
- JAK3 | c.1981G>C p.D661H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV101512900, COSV71685622; called by muse, mutect2, varscan2
- KDM4C | c.2693G>C p.R898T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs1323404836, COSV101185151, COSV67191212; called by muse, mutect2, varscan2
- KIAA1109 | c.8800C>A p.P2934T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52688645; called by mutect2, varscan2
- KLF3 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54709740; called by muse, mutect2, varscan2
- KLHL32 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs140246562, COSV65111774; called by muse, mutect2, varscan2
- KRT84 | c.1251G>C p.E417D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99230785; called by muse, mutect2
- KTN1 | c.2701C>G p.Q901E | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV63215779; called by muse, mutect2, varscan2
- LARP4 | c.1912C>A p.L638I | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53326459; called by muse, mutect2
- LMLN | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57604348; called by muse, mutect2, varscan2
- LRRIQ1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV67832158, COSV67837048; called by muse, mutect2, varscan2
- LYG2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.486); catalogued as COSV60716520; called by muse, mutect2, varscan2
- MAOA | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1280809917, COSV58644892; called by muse, mutect2, varscan2
- MFSD3 | c.948C>G p.I316M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV56742553; called by muse, mutect2, varscan2
- MFSD9 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV51495349; called by muse, mutect2, varscan2
- MGAT4C | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs753847188, COSV59836851; called by muse, mutect2, varscan2
- MKI67 | c.4476A>G p.I1492M | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.159); catalogued as COSV64076383; called by muse, mutect2
- MOV10L1 | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53177836; called by muse, mutect2, varscan2
- MS4A12 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV50015408; called by muse, mutect2, varscan2
- MSRB2 | c.294C>T p.F98= | Splice Region (SNP) | VAF 13/76 reads (17%) | catalogued as COSV64737953; called by muse, mutect2, varscan2
- MTARC2 | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247306521, COSV63766268; called by muse, mutect2
- NEIL2 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52707681; called by muse, mutect2
- NINL | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs918417293, COSV54007611; called by muse, mutect2, varscan2
- OR8B3 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1168696185, COSV100660381; called by muse, mutect2
- OSBPL5 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs146107856; called by muse, mutect2, varscan2
- PAX1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.503); catalogued as rs1321769358, COSV68273115; called by muse, mutect2, varscan2
- PCLO | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs748086704, COSV100438131, COSV61659794; called by muse, mutect2, varscan2
- PDZD4 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51250188; called by muse, mutect2, varscan2
- PEAK1 | c.4774G>C p.E1592Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56941823; called by muse, mutect2, varscan2
- PI4KA | c.6006G>A p.M2002I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99743560; called by muse, varscan2
- PIAS3 | c.1480G>C p.V494L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV57908342; called by muse, mutect2, varscan2
- PKP2 | c.1448C>G p.T483S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV50731318, COSV99297426; called by muse, mutect2
- PLEKHA2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs540927071, COSV66243391; called by muse, mutect2, varscan2
- POLR2B | c.1402C>G p.Q468E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58902326; called by muse, mutect2, varscan2
- PPFIA4 | c.1787C>A p.S596Y (on ENST00000447715; = p.S597Y on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55320354; called by muse, mutect2, varscan2
- PPP1R9A | c.1160C>G p.S387* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV56889961, COSV99194753, COSV99194970; called by muse, mutect2, varscan2
- PPP4C | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54223050; called by muse, mutect2, varscan2
- PRDM14 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99399991; called by muse, mutect2
- PRKCG | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54731405; called by muse, mutect2, varscan2
- PRKD3 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52217263; called by muse, mutect2
- PROX1 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.121); catalogued as COSV54782762; called by muse, mutect2, varscan2
- PRUNE1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as rs377500161; called by muse, mutect2, varscan2
- PTCD3 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201126831, COSV54482546; called by muse, mutect2, varscan2
- PTPN14 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs778948538, COSV65284731; called by muse, mutect2, varscan2
- PYDC2 | c.130del p.Q44Rfs*4 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs1348240779; called by mutect2, varscan2
- RAB3GAP2 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 28/128 reads (22%) | catalogued as COSV62783064; called by muse, mutect2, varscan2
- RB1 | c.571del p.L191* | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV57322835; called by mutect2, pindel, varscan2
- RBM10 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV61311605; called by muse, mutect2, varscan2
- RBSN | c.1133C>G p.T378S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV53795216; called by muse, mutect2, varscan2
- RBSN | c.1132A>T p.T378S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV53795224; called by muse, mutect2, varscan2
- RNF111 | c.1967C>G p.P656R | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV62089068; called by muse, varscan2
- RNF112 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101465401; called by muse, mutect2, varscan2
- RNF123 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as COSV57539898; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV53448943; called by muse, mutect2, varscan2
- SAXO2 | c.678A>T p.E226D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.239); catalogued as COSV59755106; called by muse, mutect2
- SCN3B | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV54800928; called by muse, mutect2, varscan2
- SDCBP | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs772737023, COSV52707243; called by muse, mutect2, varscan2
- SEC16A | c.5599G>A p.E1867K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51538185; called by muse, mutect2, varscan2
- SLC22A7 | c.947A>G p.Q316R (on ENST00000372585 / NM_153320.2; = p.Q314R on NM_006672.3) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV51485692; called by muse, mutect2, varscan2
- SLCO1B1 | c.111C>G p.S37R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV57015815; called by muse, mutect2, varscan2
- SMG7 | c.2090A>T p.Q697L | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV61633763; called by muse, mutect2, varscan2
- SOX9 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs747366415, COSV55427572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPZ1 | c.999G>C p.Q333H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as COSV57064457; called by muse, mutect2, varscan2
- SULT1A1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59090258; called by muse, mutect2, varscan2
- SUPT20H | c.1844C>T p.S615L (on ENST00000350612 / NM_001014286.3; = p.S616L on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs756283101, COSV62249265; called by muse, mutect2, varscan2
- TARBP1 | c.2714C>T p.T905I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV50200373; called by muse, mutect2, varscan2
- TDRD6 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV60178016; called by muse, mutect2, varscan2
- TFCP2L1 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99747920; called by muse, mutect2, varscan2
- TGM7 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.024); catalogued as COSV71773094; called by muse, mutect2, varscan2
- TICAM1 | c.1118C>G p.S373* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99941043; called by muse, varscan2
- TMCC2 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs937307331, COSV100405152; called by muse, mutect2, varscan2
- TNF | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs772270241, COSV69305263; called by muse, mutect2, varscan2
- TNFRSF8 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99821243; called by muse, mutect2, varscan2
- TNXB | c.8080G>A p.D2694N (on ENST00000647633; = p.D2447N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.971); catalogued as COSV64487299; called by muse, mutect2
- TRIM3 | c.459T>A p.D153E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.222); catalogued as COSV61985355; called by muse, mutect2, varscan2
- TRIM36 | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1394598978, COSV56692740; called by muse, mutect2, varscan2
- TRIM67 | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as COSV100792223, COSV64160008, COSV64160125; called by muse, mutect2, varscan2
- TRIP4 | c.1706G>C p.G569A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV56032779; called by muse, mutect2, varscan2
- TRMT1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52835670; called by muse, mutect2, varscan2
- TSC22D1 | c.2546C>G p.T849R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV71776183; called by muse, mutect2, varscan2
- TTN | c.60710G>A p.G20237E (on ENST00000591111; = p.G12813E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV60285127; called by muse, varscan2
- UBP1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV52147333; called by muse, mutect2, varscan2
- UCP1 | c.203C>G p.T68R | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV53767625, COSV53768508; called by muse, mutect2, varscan2
- USP14 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1345805593, COSV55283109; called by muse, mutect2, varscan2
- USP34 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as rs970997261, COSV68401706; called by muse, mutect2, varscan2
- USP37 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99294227; called by muse, mutect2
- USP7 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100784080; called by muse, mutect2
- VPS16 | c.2485A>C p.I829L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV66798298; called by muse, mutect2, varscan2
- WDR26 | c.760C>G p.R254G (on ENST00000414423 / NM_001379403.1; = p.R154G on NM_025160.7) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.073); catalogued as COSV54359324; called by muse, mutect2
- WWP1 | c.2696A>G p.Y899C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752555908, COSV55363102; called by muse, mutect2, varscan2
- XG | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV66986076; called by muse, mutect2, varscan2
- XPO4 | c.3412G>C p.E1138Q | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV55012025; called by muse, mutect2, varscan2
- YME1L1 | c.1217C>T p.S406F (on ENST00000326799 / NM_139312.3; = p.S349F on NM_014263.4) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58761194; called by muse, mutect2, varscan2
- ZDBF2 | c.5254T>G p.C1752G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV65629224; called by muse, mutect2, varscan2
- ZFP28 | c.1090C>G p.H364D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV56737705; called by muse, mutect2, varscan2
- ZFP82 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as COSV67566438; called by muse, mutect2, varscan2
- ZNF12 | c.1454G>C p.R485T (on ENST00000405858 / NM_016265.4; = p.R447T on NM_006956.3) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV100703633, COSV61245349; called by muse, varscan2
- ZNF12 | c.1382G>C p.G461A (on ENST00000405858 / NM_016265.4; = p.G423A on NM_006956.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs900846058, COSV61245356; called by muse, varscan2
- ZNF20 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV62000345; called by muse, mutect2, varscan2
- ZNF626 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs376276756, COSV52482558; called by muse, mutect2, varscan2
- ZNF780A | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); catalogued as rs375366451; called by muse, mutect2, varscan2
- ZZEF1 | c.2804C>G p.T935S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV67559785; called by muse, mutect2, varscan2
- ARID1A | c.6306del p.S2104Pfs*31 | Frame Shift Del (DEL) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- HMCN1 | c.8028del p.P2677Qfs*8 | Frame Shift Del (DEL) | VAF 46/127 reads (36%) | called by mutect2, pindel, varscan2
- PHF1 | c.16del p.R6Gfs*2 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- PRRC1 | c.362del p.L121Yfs*34 | Frame Shift Del (DEL) | VAF 27/136 reads (20%) | called by mutect2, pindel, varscan2
- SKIL | c.532_545delinsCAG p.F178Qfs*7 | Frame Shift Del (DEL) | VAF 24/135 reads (18%) | called by pindel, varscan2*
- ZFYVE19 | c.354del p.N119Tfs*14 (on ENST00000355341 / NM_001077268.2; = p.N109Tfs*14 on NM_032850.5) | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- ZNF423 | c.1786_1788del p.H596del (on ENST00000563137 / NM_001379286.1; = p.H588del on NM_015069.4) | In Frame Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- ZNHIT3 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ACVR1B | c.1350G>A p.Q450= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV57779616; called by muse, mutect2, varscan2
- ADAM11 | c.447C>G p.L149= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV52349338; called by muse, mutect2, varscan2
- AMPD3 | c.1491C>T p.F497= (on ENST00000396553 / NM_001025389.2; = p.F506= on NM_000480.3) | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs780789937, COSV67332160; called by muse, mutect2, varscan2
- ANKRD17 | c.7284G>A p.G2428= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV58226479; called by muse, mutect2, varscan2
- ATP2B3 | c.1512G>A p.L504= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as COSV54858848; called by muse, mutect2, varscan2
- CDH23 | c.1557C>T p.A519= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99819797; called by muse, mutect2
- CLCN6 | c.423C>T p.V141= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV56742633; called by muse, mutect2, varscan2
- CMPK2 | c.771C>T p.I257= | Silent (SNP) | VAF 60/109 reads (55%) | catalogued as rs371005529; called by muse, mutect2, varscan2
- CREB5 | c.369C>T p.P123= (on ENST00000357727 / NM_182898.4; = p.P116= on NM_004904.3) | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV63227368; called by muse, mutect2, varscan2
- CRTC1 | c.732G>T p.G244= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs954956396, COSV58718979, COSV58722489; called by muse, mutect2, varscan2
- CTNND2 | c.483A>G p.K161= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV58919207; called by muse, mutect2, varscan2
- DMXL2 | c.6328C>T p.L2110= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV51854191; called by muse, mutect2, varscan2
- EFTUD2 | c.543C>T p.I181= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs764108448, COSV68184507; called by muse, mutect2, varscan2
- FIGN | c.1662A>G p.G554= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV60770906; called by muse, mutect2, varscan2
- FILIP1 | c.699C>T p.L233= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV52738819; called by muse, mutect2, varscan2
- FN1 | c.6315C>A p.L2105= (on ENST00000359671 / NM_001365524.2; = p.L2015= on NM_212476.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV60561614; called by muse, mutect2, varscan2
- GJA5 | c.84C>G p.V28= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99605429; called by muse, mutect2
- GPAA1 | c.627G>A p.S209= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs376959806; called by muse, mutect2, varscan2
- GRM1 | c.534C>T p.F178= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as rs1376955627, COSV51109245; called by muse, mutect2, varscan2
- IL7R | c.87C>T p.D29= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs370292681; called by muse, mutect2, varscan2
- KHNYN | c.1512C>T p.L504= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV52162982; called by muse, mutect2, varscan2
- LINGO2 | c.465G>A p.L155= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1360383338, COSV58063309; called by muse, mutect2, varscan2
- LRGUK | c.27G>A p.L9= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1301077843, COSV53642611; called by muse, mutect2, varscan2
- LRRIQ4 | c.342C>T p.V114= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV61620025; called by muse, varscan2
- LRRIQ4 | c.375C>G p.L125= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV61620030; called by muse, varscan2
- LRRN2 | c.582C>T p.L194= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV65784479; called by muse, mutect2, varscan2
- MROH1 | c.1407C>G p.T469= | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- MX2 | c.639C>T p.I213= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV58098920; called by muse, mutect2, varscan2
- MYO18A | c.1482C>T p.I494= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV62872232; called by muse, mutect2, varscan2
- NRP2 | c.378C>T p.S126= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs1346019715, COSV55934271; called by muse, mutect2, varscan2
- OR14J1 | c.882C>T p.S294= | Silent (SNP) | VAF 81/216 reads (38%) | catalogued as COSV65845932; called by muse, mutect2, varscan2
- PARVG | c.97C>T p.L33= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV63562647; called by muse, mutect2, varscan2
- PTPRC | c.3429C>T p.V1143= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs201509862, COSV100722910, COSV61414617; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAPGEF1 | c.1353T>C p.D451= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV64701749; called by mutect2, varscan2
- SATB1 | c.775C>T p.L259= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100113011; called by muse, mutect2
- SLC5A11 | c.696G>A p.L232= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as rs1359064986, COSV61742029; called by muse, mutect2, varscan2
- SLITRK2 | c.2499C>T p.L833= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV59422616; called by muse, mutect2, varscan2
- SUN5 | c.1020G>A p.V340= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs1341671302, COSV62182261; called by muse, mutect2, varscan2
- SYNGAP1 | c.2049C>T p.I683= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs536234142, COSV53385708; called by muse, mutect2, varscan2
- TGM5 | c.1203T>G p.A401= (on ENST00000220420 / NM_201631.4; = p.A319= on NM_004245.4) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV55011798; called by muse, mutect2, varscan2
- TNXB | c.8082C>T p.D2694= (on ENST00000647633; = p.D2447= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs1188044301, COSV64487282; called by muse, mutect2
- TRIM55 | c.528C>T p.I176= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs149301931; called by muse, mutect2, varscan2
- VEPH1 | c.2184C>T p.V728= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100747309, COSV62881869; called by muse, mutect2, varscan2
- ZNF283 | c.639G>T p.G213= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV61032428; called by muse, mutect2, varscan2
- ZNF862 | c.2634A>T p.A878= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV56225731; called by muse, mutect2, varscan2
- ACOT11 | c.1629+978C>G | Intron (SNP) | VAF 41/146 reads (28%) | catalogued as COSV56365958; called by muse, mutect2, varscan2
- AP003393.1 | n.515-754C>T | Intron (SNP) | VAF 10/37 reads (27%) | catalogued as COSV58228224; called by muse, mutect2, varscan2
- CTBP1 | chr4:1251038 G>T | 5'Flank (SNP) | VAF 12/40 reads (30%) | catalogued as rs774614634; called by muse, mutect2, varscan2
- FAM83D | chr20:38926370 G>C | 5'Flank (SNP) | VAF 11/45 reads (24%) | catalogued as COSV54158829; called by muse, mutect2, varscan2
- FSD2 | c.*3279C>G | 3'UTR (SNP) | VAF 22/151 reads (15%) | catalogued as COSV100575070; called by muse, mutect2, varscan2
- FUT7 | chr9:137034947 G>A | 5'Flank (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- RMDN2 | c.452+21719C>G | Intron (SNP) | VAF 37/84 reads (44%) | catalogued as COSV52228554; called by muse, mutect2, varscan2
